TARGET case TARGET-10-PANKMB — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/27cb0f75-8188-40a4-b2c1-e3e7d59f60f5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (1 sample)
- Sample TARGET-10-PANKMB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 4175
- WBC at Diagnosis: 110
- CNS Status at Diagnosis: CNS 2
- MRD Day 29: 0.024
- MRD Day 29 Sensitivity: 0.001
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 64
- BMA Blasts Day 15: 3
- BMA Blasts Day 29: 0
- Karyotype: 47,XX,del(3)(p21),del(5)(q13q22),del(7)(q32),del(9)(p21),del(10)(q23),del(12)(p12),del(14)(q11.2),der(16)t(10;16)(q23;p13)t(14;16)(q11.2;q24),dup(21)(q?),+dup(21)(q?)[10]/46,XX[10]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
